Somatic mutation profile of tumor specimen TCGA-EY-A1GI-01A (aliquot TCGA-EY-A1GI-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 52.3 years (19,117 days).
Specimen TCGA-EY-A1GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2764c376-39a8-4dac-9cce-fbeebf77fbc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GI-10A (Blood Derived Normal), aliquot TCGA-EY-A1GI-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5e4b53f-1417-423f-b3c5-d65b25daf8f6

The open-access MAF lists 5,087 somatic variants for this specimen: 4,087 protein-altering or splice-affecting, 874 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,410, Silent 874, Nonsense Mutation 569, Intron 53, Splice Site 53, RNA 31, Splice Region 25, 3'UTR 19, Frame Shift Ins 13, 3'Flank 10, 5'Flank 10, Nonstop Mutation 7.

Variants (750 of 5,087; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as rs1411638309, COSV56852422; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs397507646, CM062477, COSV66461936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRWD3 | c.3718C>T p.R1240* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as rs878853055, COSV64743451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CARS1 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs764965330, COSV99543152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL5A2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs563606558, COSV100880593; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- COLEC10 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as rs149010496; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, varscan2
- DHCR7 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs756564881, COSV100832031; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.5586+1G>A p.X1862_splice | Splice Site (SNP) | VAF 29/62 reads (47%) | catalogued as rs1557292599, COSV100821209; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as rs1557320151, CM098412, COSV63744696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52781024; called by muse, mutect2, varscan2
- EVC2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs137852924, CM030650, COSV100186396; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8326C>T p.R2776* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs137854466, CM940772, COSV57312804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- GANAB | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs1210158408, COSV99642116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCTD7 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.225); catalogued as rs387907260, CM124822, COSV99299220; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- LMBRD1 | c.1222C>T p.R408* (on ENST00000649011; = p.R386* on NM_018368.4) | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs1380343985, COSV65296997; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5664C>A p.F1888L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63869154, COSV63870934; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs1485445500, COSV58629409; ClinVar: pathogenic; called by muse, mutect2
- OTC | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as rs66521141, CM001741, CM001742, COSV99234242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as rs72558466, CM930533, COSV99234243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 12/19 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTCH1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs863224650, CM066203, COSV59462369, COSV59487305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.529T>G p.Y177D | Missense Mutation (SNP) | VAF 24/53 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV64291876, COSV64310559, COSV64310717; called by muse, mutect2, varscan2
- PTEN | c.531T>G p.Y177* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); catalogued as rs878853012, COSV100909304, COSV64289866, COSV64296956; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- RASA1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1463885690, CM083070, COSV57192389; ClinVar: pathogenic; called by muse, varscan2
- RYR2 | c.13528G>A p.A4510T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs397516510, CM043079, COSV63693754; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SBF2 | c.3526C>T p.R1176* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as rs774667470, COSV99814989; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | catalogued as COSV100229198; called by muse, mutect2, varscan2
- AAR2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs781449292, COSV100299373; called by muse, mutect2, varscan2
- AASDHPPT | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99593369; called by muse, mutect2, varscan2
- ABCA10 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52220260, COSV99289003; called by muse, mutect2, varscan2
- ABCA12 | c.3556G>A p.A1186T (on ENST00000272895 / NM_173076.3; = p.A868T on NM_015657.3) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV99790994; called by muse, mutect2, varscan2
- ABCA12 | c.1782G>A p.E594= (on ENST00000272895 / NM_173076.3; = p.E276= on NM_015657.3) | Splice Region (SNP) | VAF 17/37 reads (46%) | catalogued as rs376960143; called by muse, mutect2, varscan2
- ABCA12 | c.1484C>A p.S495Y (on ENST00000272895 / NM_173076.3; = p.S177Y on NM_015657.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV99791001; called by muse, mutect2, varscan2
- ABCA13 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.225); catalogued as rs762870247, COSV101330118; called by muse, mutect2, varscan2
- ABCA13 | c.3641A>C p.K1214T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs767336028, COSV70036052; called by muse, mutect2
- ABCA13 | c.4024G>A p.D1342N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.208); catalogued as COSV101330119, COSV70043390; called by mutect2, varscan2
- ABCA13 | c.7758G>T p.K2586N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.027); catalogued as rs1366033404, COSV101447069; called by muse, mutect2, varscan2
- ABCA13 | c.13344G>T p.K4448N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV68942924; called by muse, mutect2, varscan2
- ABCA2 | c.508A>G p.S170G (on ENST00000614293; = p.S140G on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99688063; called by muse, mutect2, varscan2
- ABCA5 | c.4624G>T p.E1542* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV101201205, COSV99077696; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCA7 | c.4753C>A p.L1585I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as COSV99566309; called by muse, mutect2, varscan2
- ABCA9 | c.1669A>G p.I557V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as rs1333533189, COSV100383308; called by muse, mutect2, varscan2
- ABCB1 | c.3298G>T p.E1100* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV55967003, COSV99713627; called by muse, mutect2, varscan2
- ABCB1 | c.2198C>A p.S733* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99713628; called by muse, mutect2, varscan2
- ABCB1 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99712004; called by muse, mutect2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB5 | c.1621C>T p.R541* (on ENST00000404938 / NM_001163941.2; = p.R96* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV51702825; called by muse, mutect2, varscan2
- ABCB7 | c.956G>T p.R319I (on ENST00000373394 / NM_001271696.3; = p.R320I on NM_004299.6) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99504591; called by muse, mutect2, varscan2
- ABCB8 | c.1428C>A p.N476K (on ENST00000297504 / NM_001282291.2; = p.N459K on NM_007188.5) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV52507849, COSV52509173, COSV99874722; called by muse, mutect2, varscan2
- ABCC11 | c.3096G>T p.Q1032H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62321992; called by muse, mutect2, varscan2
- ABCC11 | c.2973G>T p.E991D | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.459); catalogued as COSV100750979; called by muse, mutect2, varscan2
- ABCC2 | c.2587C>A p.L863I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100966554; called by muse, mutect2, varscan2
- ABCD2 | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369703833, COSV100429650; called by muse, varscan2
- ABCD2 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100429652, COSV58050597; called by muse, varscan2
- ABCD2 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58049521, COSV58055009, COSV58055073; called by muse, mutect2, varscan2
- ABCD3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1170362881, COSV59865610; called by muse, mutect2, varscan2
- ABCF1 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs746847046, COSV100400927; called by muse, mutect2, varscan2
- ABCF2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99734677; called by muse, mutect2, varscan2
- ABCG2 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs1480156055, COSV99419670; called by muse, mutect2, varscan2
- ABCG2 | c.1511A>G p.D504G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs751507819, COSV99419673; called by muse, mutect2, varscan2
- ABHD14B | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.075); catalogued as COSV99865497; called by muse, mutect2, varscan2
- ABHD4 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs746220551, COSV53530114; called by muse, mutect2, varscan2
- ABHD5 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1358271126, COSV50006309; called by muse, mutect2, varscan2
- ABLIM1 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.223); catalogued as COSV99522400; called by muse, mutect2, varscan2
- AC004593.2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765588; called by muse, mutect2, varscan2
- AC008397.2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as rs767249358, COSV62748376; called by muse, varscan2
- AC020907.6 | c.332C>G p.A111G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV100032748; called by muse, mutect2, varscan2
- AC092143.1 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100205965; called by muse, mutect2, varscan2
- AC100868.1 | c.1367C>A p.P456Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51844815, COSV99226469; called by muse, mutect2, varscan2
- AC131160.1 | c.1036T>G p.F346V | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100590634; called by muse, mutect2, varscan2
- AC244197.3 | c.893A>C p.E298A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV100558094; called by muse, mutect2, varscan2
- AC244197.3 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as CM1111068, CS961601, COSV100558097, COSV61714248; called by muse, mutect2, varscan2
- ACADL | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs375084422, CM112334, COSV52052059, COSV52052222; called by muse, mutect2, varscan2
- ACAP1 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs766898275, COSV99341844; called by muse, varscan2
- ACER3 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53602191; called by muse, mutect2, varscan2
- ACOT8 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99467702; called by muse, varscan2
- ACOT9 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100321360; called by muse, varscan2
- ACOT9 | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100321361; called by muse, varscan2
- ACOX2 | c.1192T>G p.S398A | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV100250235; called by muse, mutect2, varscan2
- ACOXL | c.1585G>A p.E529K (on ENST00000389811 / NM_001371254.1; = p.E499K on NM_001142807.4) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV101095465; called by muse, mutect2, varscan2
- ACSBG1 | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752742288, COSV99357628; called by muse, mutect2, varscan2
- ACSL6 | c.1123G>A p.D375N (on ENST00000379240; = p.D400N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57301868; called by muse, mutect2, varscan2
- ACSM2B | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1457653822, COSV61657878; called by muse, mutect2, varscan2
- ACSM4 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101257248; called by muse, mutect2, varscan2
- ACSM4 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs780121588, COSV101257250; called by muse, mutect2, varscan2
- ACTA1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV64204077; called by muse, mutect2, varscan2
- ACTL6A | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV66999088; called by muse, mutect2, varscan2
- ACTL6B | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV99355654; called by muse, mutect2, varscan2
- ACTN4 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs763051766, COSV53147827; called by muse, mutect2
- ACTR5 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs768522307, COSV54759775; called by muse, mutect2, varscan2
- ACTR6 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV99498691; called by muse, mutect2, varscan2
- ACTRT1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV64419395; called by muse, mutect2, varscan2
- ACTRT2 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65759018; called by muse, mutect2, varscan2
- ACVR1B | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 29/64 reads (45%) | catalogued as COSV99231627; called by muse, mutect2, varscan2
- ACVR1B | c.1013C>A p.S338* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | catalogued as COSV57779492; called by muse, mutect2, varscan2
- ACVR1C | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99694878; called by muse, mutect2, varscan2
- ACVR2A | c.1433G>T p.R478I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54022039; called by muse, mutect2, varscan2
- ADAD1 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56641122, COSV56642830; called by muse, mutect2, varscan2
- ADAM19 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1159665258, COSV99977856; called by muse, mutect2, varscan2
- ADAM21 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99961235; called by muse, mutect2, varscan2
- ADAM22 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99717608; called by muse, mutect2, varscan2
- ADAM29 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100822139, COSV63664593; called by muse, mutect2, varscan2
- ADAM29 | c.2009G>T p.R670I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV100822144; called by muse, varscan2
- ADAMDEC1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1207275267, COSV99836187; called by muse, mutect2, varscan2
- ADAMTS1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs762654704, COSV99536347; called by muse, mutect2, varscan2
- ADAMTS1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568811671, COSV53173056; called by muse, mutect2, varscan2
- ADAMTS12 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372986935; called by muse, mutect2, varscan2
- ADAMTS16 | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372733019; called by muse, mutect2, varscan2
- ADAMTS18 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as rs555580484, COSV99273546; called by muse, mutect2, varscan2
- ADAMTS3 | c.3524C>A p.S1175* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs764000631, COSV99711645; called by muse, varscan2
- ADAMTS3 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV54394298, COSV99711647; called by muse, mutect2, varscan2
- ADAMTS5 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs777065435, COSV53177958; called by muse, mutect2, varscan2
- ADAMTS6 | c.1913A>C p.N638T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66859821; called by muse, mutect2, varscan2
- ADAMTS9 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV55781222, COSV99899892; called by muse, mutect2, varscan2
- ADAMTS9 | c.1006T>G p.L336V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs769277488, COSV99899893; called by muse, mutect2, varscan2
- ADARB2 | c.1725C>A p.F575L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.27); catalogued as COSV101184570; called by muse, mutect2, varscan2
- ADCY4 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs374008973; called by muse, mutect2, varscan2
- ADCY8 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53908135; called by muse, mutect2, varscan2
- ADGRB1 | c.3535G>A p.V1179I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as rs1001081185, COSV60100861; called by muse, mutect2, varscan2
- ADGRB3 | c.1268G>T p.R423I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101001261; called by muse, mutect2, varscan2
- ADGRB3 | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs761863915, COSV99486169; called by muse, mutect2, varscan2
- ADGRE1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs758217934, COSV51673273; called by muse, mutect2, varscan2
- ADGRE1 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.156); catalogued as rs375499219; called by muse, mutect2, varscan2
- ADGRE5 | c.1315C>A p.L439I (on ENST00000242786 / NM_078481.4; = p.L346I on NM_001784.5) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV99663079; called by muse, mutect2, varscan2
- ADGRF1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143178573, COSV51947538; called by muse, mutect2, varscan2
- ADGRF4 | c.502A>C p.K168Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV99348693; called by muse, mutect2, varscan2
- ADGRF4 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV51950045, COSV51951782; called by muse, mutect2, varscan2
- ADGRF4 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.513); catalogued as rs200623239, COSV51949975; called by muse, mutect2, varscan2
- ADGRF5 | c.1116T>G p.I372M | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV99346035; called by muse, mutect2, varscan2
- ADGRF5 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.129); catalogued as COSV99346038; called by muse, mutect2, varscan2
- ADGRG4 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV99796091; called by muse, mutect2, varscan2
- ADGRG4 | c.6260C>A p.S2087Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs1172690563, COSV99796095; called by muse, mutect2, varscan2
- ADGRL2 | c.3379C>T p.R1127C (on ENST00000370717 / NM_001366005.1; = p.R1114C on NM_012302.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775087345, COSV54673990, COSV54685771; called by muse, mutect2
- ADGRL3 | c.458A>C p.K153T (on ENST00000506720 / NM_001322402.2; = p.K85T on NM_015236.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101547293; called by muse, mutect2, varscan2
- ADGRL4 | c.961A>C p.N321H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV100876269; called by muse, mutect2, varscan2
- ADGRL4 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100875946, COSV66066425; called by muse, mutect2, varscan2
- ADGRV1 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV101316218; called by muse, mutect2, varscan2
- ADGRV1 | c.5957G>T p.R1986I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101316219; called by muse, mutect2, varscan2
- ADGRV1 | c.14669T>G p.F4890C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101316220; called by muse, mutect2, varscan2
- ADNP | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1186714720, COSV100823800; called by muse, mutect2, varscan2
- ADTRP | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99995378; called by muse, mutect2, varscan2
- AFF3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs190577667, COSV57838935; called by mutect2, varscan2
- AFF3 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100419604; called by muse, mutect2, varscan2
- AFTPH | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV53221133, COSV99480966; called by muse, mutect2, varscan2
- AFTPH | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as rs547250681, COSV99480974; called by muse, varscan2
- AGBL2 | c.2076C>A p.F692L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100101897; called by muse, mutect2, varscan2
- AGBL4 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as COSV100484475, COSV61893435; called by muse, mutect2, varscan2
- AGGF1 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100462060; called by muse, mutect2, varscan2
- AGGF1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as rs1489043011, COSV100462063; called by muse, mutect2, varscan2
- AGO2 | c.1964A>C p.K655T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99596087; called by muse, mutect2, varscan2
- AGPAT3 | c.179-1G>A p.X60_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99377688; called by muse, mutect2, varscan2
- AGPAT4 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100211718; called by muse, mutect2
- AGXT2 | c.1195A>C p.K399Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99183796; called by muse, mutect2, varscan2
- AGXT2 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99183798; called by muse, mutect2, varscan2
- AHCTF1 | c.1321C>T p.R441C (on ENST00000366508; = p.R415C on NM_015446.5) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773026706, COSV100403758, COSV58252915; called by muse, mutect2, varscan2
- AHNAK | c.13067C>T p.A4356V | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV57204621; called by muse, mutect2, varscan2
- AHNAK | c.9109G>T p.G3037* | Nonsense Mutation (SNP) | VAF 45/135 reads (33%) | catalogued as COSV99948525; called by muse, mutect2, varscan2
- AHNAK | c.7122C>A p.F2374L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); catalogued as COSV99948527; called by muse, mutect2, varscan2
- AHNAK2 | c.14047G>A p.D4683N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs375463111; called by muse, varscan2
- AHNAK2 | c.1983A>C p.Q661H | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.26); catalogued as COSV60922379; called by muse, mutect2, varscan2
- AHSA1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99376110; called by muse, mutect2, varscan2
- AICDA | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs370700027; ClinVar: uncertain significance; called by muse, varscan2
- AIDA | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as rs1228683651, COSV100388317; called by muse, mutect2, varscan2
- AIFM1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV99781209; called by muse, mutect2, varscan2
- AIMP2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756425703, COSV99552132; called by muse, mutect2, varscan2
- AK7 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs752126253, COSV99967403; called by muse, mutect2, varscan2
- AK8 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100050303; called by muse, mutect2, varscan2
- AKAP11 | c.4286G>T p.R1429I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1308479533, COSV50293081; called by muse, mutect2, varscan2
- AKAP4 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100654317; called by muse, mutect2, varscan2
- AKAP5 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs370872498; called by muse, varscan2
- AKAP5 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV57742724; called by muse, mutect2, varscan2
- AKAP7 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as rs754751702, COSV53834357; called by muse, mutect2, varscan2
- AKAP9 | c.1632T>G p.I544M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100662696; called by muse, mutect2, varscan2
- AKAP9 | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100662697; called by muse, varscan2
- AKAP9 | c.2328G>T p.E776D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV100662698; called by muse, mutect2, varscan2
- AKAP9 | c.4279A>C p.N1427H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100662699; called by muse, mutect2, varscan2
- AKAP9 | c.6386T>G p.V2129G (on ENST00000359028; = p.V2097G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100662703; called by muse, mutect2, varscan2
- AKAP9 | c.6875C>T p.S2292F (on ENST00000359028; = p.S2268F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV100662705; called by muse, mutect2, varscan2
- AKAP9 | c.11206C>T p.R3736* (on ENST00000359028; = p.R3712* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as rs1234676587, COSV62354774; called by muse, mutect2, varscan2
- AKNAD1 | c.1847A>C p.N616T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100645720; called by muse, mutect2, varscan2
- AKNAD1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.112); catalogued as COSV62203323; called by muse, mutect2, varscan2
- AKR1E2 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1016857511, COSV100033602; called by muse, mutect2, varscan2
- AKT3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV55612501, COSV99796232; called by muse, mutect2, varscan2
- AL592490.1 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV101308174; called by muse, mutect2, varscan2
- AL645922.1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.215); catalogued as COSV54962197; called by muse, varscan2
- ALDH1A3 | c.431T>C p.F144S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100320541; called by muse, mutect2, varscan2
- ALDH5A1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as rs772361710, COSV100708811; called by muse, mutect2, varscan2
- ALDH5A1 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100708859; called by muse, mutect2, varscan2
- ALDH6A1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs201935817, COSV63246832; called by muse, mutect2, varscan2
- ALG10 | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 97/240 reads (40%) | catalogued as COSV99848252; called by muse, mutect2, varscan2
- ALG10B | c.1114T>G p.L372V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.151); catalogued as COSV100439941; called by muse, mutect2, varscan2
- ALG3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.338); catalogued as COSV56611666; called by muse, mutect2, varscan2
- ALG8 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as rs1218835499, COSV100220193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALLC | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV52997777; called by muse, mutect2
- ALMS1 | c.10542C>A p.F3514L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV100043108, COSV52521743; called by muse, mutect2, varscan2
- ALPP | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs753056192, COSV67395812; called by muse, mutect2, varscan2
- ALS2CL | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs144181784, COSV100015192; called by muse, mutect2, varscan2
- ALX1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs144593505; called by muse, mutect2, varscan2
- AMBN | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59825360; called by muse, mutect2, varscan2
- AMBP | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs377277500; called by muse, mutect2, varscan2
- AMER2 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV100766326; called by muse, mutect2, varscan2
- AMMECR1L | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1410305913, COSV55759965; called by muse, mutect2, varscan2
- AMN1 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV99861618; called by muse, mutect2, varscan2
- AMPD1 | c.1883G>A p.G628D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815136; called by muse, mutect2, varscan2
- AMY2B | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as COSV100796402; called by muse, mutect2, varscan2
- AMZ2 | c.447A>C p.Q149H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100703190; called by muse, mutect2, varscan2
- ANAPC5 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55842386, COSV99946345; called by muse, mutect2, varscan2
- ANGPT4 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV67922810; called by muse, mutect2, varscan2
- ANGPTL5 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100527897; called by muse, mutect2, varscan2
- ANK1 | c.3984G>T p.K1328N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99226071; called by muse, mutect2, varscan2
- ANK2 | c.5278G>T p.E1760* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100002895, COSV52145437; called by muse, mutect2, varscan2
- ANK2 | c.9646G>T p.E3216* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100002897; called by muse, mutect2, varscan2
- ANK3 | c.9422C>A p.P3141H | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV99781111; called by muse, mutect2, varscan2
- ANK3 | c.7543C>A p.L2515I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1266079762, COSV55082059, COSV99781928; called by muse, mutect2, varscan2
- ANK3 | c.4279A>G p.T1427A (on ENST00000280772 / NM_001320874.2; = p.T561A on NM_001149.3) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV99781115; called by muse, mutect2, varscan2
- ANK3 | c.3910G>T p.E1304* (on ENST00000280772 / NM_001320874.2; = p.E438* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV55068402, COSV99781120; called by muse, mutect2, varscan2
- ANK3 | c.3056G>A p.R1019Q (on ENST00000280772 / NM_001320874.2; = p.R153Q on NM_001149.3) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199911843, COSV99778997; called by muse, mutect2
- ANKEF1 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65693464, COSV65693718; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7723G>T p.E2575* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99783888; called by muse, mutect2, varscan2
- ANKIB1 | c.755T>G p.L252R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99729512; called by muse, mutect2, varscan2
- ANKLE1 | c.1178A>G p.D393G (on ENST00000394458; = p.D339G on NM_152363.6) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV100845757; called by muse, mutect2, varscan2
- ANKRD1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as rs1130407, COSV100792313; called by muse, mutect2, varscan2
- ANKRD11 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1323661347, COSV56359151; called by muse, mutect2, varscan2
- ANKRD12 | c.1770C>A p.F590L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs199694208, COSV100041716; called by muse, varscan2
- ANKRD12 | c.2169del p.K723Nfs*45 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs1469889281; called by mutect2, varscan2
- ANKRD13A | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99924062; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2013C>A p.F671L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs1381986024; called by muse, varscan2
- ANKRD20A4P | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100628591; called by mutect2, varscan2
- ANKRD26 | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373167535; called by muse, mutect2, varscan2
- ANKRD26 | c.2532G>T p.L844F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101063313; called by muse, mutect2, varscan2
- ANKRD27 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs769727812, COSV100042643, COSV60133705; called by muse, mutect2, varscan2
- ANKRD27 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as COSV100042990; called by muse, mutect2, varscan2
- ANKRD30A | c.1040C>A p.S347Y (on ENST00000611781; = p.S291Y on NM_052997.2) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.962); catalogued as COSV100653080; called by muse, mutect2, varscan2
- ANKRD30A | c.1774G>A p.D592N (on ENST00000611781; = p.D536N on NM_052997.2) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.441); catalogued as COSV100654034, COSV64613505; called by muse, mutect2, varscan2
- ANKRD30A | c.2982G>T p.K994N (on ENST00000611781; = p.K938N on NM_052997.2) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64606049, COSV64610801; called by muse, mutect2
- ANKRD30A | c.3826G>T p.E1276* (on ENST00000611781; = p.E1220* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100652545, COSV100654461; called by muse, mutect2, varscan2
- ANKRD40 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99560577; called by muse, mutect2, varscan2
- ANKRD45 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.142); catalogued as COSV60962385; called by muse, mutect2, varscan2
- ANKRD50 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs1308269574, COSV101538998; called by muse, mutect2, varscan2
- ANKS1A | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV100832137; called by muse, mutect2, varscan2
- ANKS1B | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV61334452; called by muse, mutect2, varscan2
- ANO2 | c.2413G>T p.G805* (on ENST00000356134 / NM_001278597.3; = p.G809* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100501651; called by muse, mutect2, varscan2
- ANO3 | c.1254C>A p.F418L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56783836, COSV99884145; called by muse, mutect2, varscan2
- ANO4 | c.823G>T p.E275* (on ENST00000392977 / NM_001286615.2; = p.E240* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100153328, COSV100154110; called by muse, mutect2, varscan2
- ANO4 | c.2337T>G p.I779M (on ENST00000392977 / NM_001286615.2; = p.I744M on NM_178826.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100153329; called by muse, mutect2, varscan2
- ANO4 | c.2544C>A p.F848L (on ENST00000392977 / NM_001286615.2; = p.F813L on NM_178826.4) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54591783; called by muse, varscan2
- ANO4 | c.2555C>T p.P852L (on ENST00000392977 / NM_001286615.2; = p.P817L on NM_178826.4) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV100153331; called by muse, varscan2
- ANO6 | c.689T>G p.F230C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV100263577; called by muse, mutect2, varscan2
- ANOS1 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99391141; called by muse, mutect2, varscan2
- ANP32D | c.121T>A p.F41I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99874361; called by muse, mutect2, varscan2
- ANPEP | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs373325407; called by muse, mutect2, varscan2
- ANTXR2 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99786701; called by muse, mutect2, varscan2
- ANXA1 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99974007; called by muse, mutect2, varscan2
- ANXA10 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as rs374810057; called by muse, mutect2, varscan2
- ANXA11 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs149646596; called by muse, mutect2, varscan2
- ANXA5 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396794753, COSV56640132; called by muse, mutect2, varscan2
- ANXA9 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs775255778, COSV64484258; called by muse, mutect2, varscan2
- AOX1 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV101022134; called by muse, mutect2, varscan2
- AP1AR | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV99914256; called by muse, mutect2, varscan2
- AP3B1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1381722917, COSV99671961; called by muse, mutect2, varscan2
- AP3S1 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100372851; called by muse, mutect2, varscan2
- AP4E1 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771128366, COSV99956881; called by muse, mutect2, varscan2
- AP5Z1 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100804189; called by muse, mutect2, varscan2
- APBB1 | c.1589T>C p.V530A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100194200; called by muse, mutect2, varscan2
- APBB1 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100194201; called by muse, mutect2, varscan2
- APCDD1 | c.280T>C p.S94P | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100789993; called by muse, mutect2, varscan2
- APEX2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs749036434, COSV66623956; called by muse, mutect2, varscan2
- APLNR | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs749277146, COSV57241999; called by muse, mutect2, varscan2
- APOA1 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs1373700967, CM108780, COSV52635247; called by muse, mutect2, varscan2
- APOA2 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV99248074; called by muse, mutect2, varscan2
- APOA5 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV99911395; called by muse, varscan2
- APOB | c.11107C>A p.R3703S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV51932917, COSV99266703; called by muse, mutect2, varscan2
- APOBEC2 | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV55142035; called by muse, mutect2, varscan2
- APOH | c.885A>C p.K295N | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV99235606, COSV99235881; called by muse, mutect2, varscan2
- APOL6 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs527259076, COSV101291004; called by muse, mutect2, varscan2
- APOLD1 | c.687G>T p.K229N (on ENST00000326765 / NM_001130415.2; = p.K198N on NM_030817.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100458814; called by muse, mutect2, varscan2
- APP | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382239795, COSV60994133; called by muse, mutect2, varscan2
- AQP9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54967982; called by muse, varscan2
- AQP9 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99583069; called by muse, varscan2
- ARAF | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99283342; called by muse, mutect2, varscan2
- ARAP2 | c.1888A>C p.I630L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV100394954; called by muse, mutect2, varscan2
- AREL1 | c.471T>G p.I157M | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV100707628; called by muse, mutect2, varscan2
- ARFGEF1 | c.5458C>T p.R1820C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51584143; called by muse, mutect2, varscan2
- ARFGEF1 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as COSV99143360; called by muse, mutect2, varscan2
- ARFRP1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs762011290, COSV99423172; called by muse, mutect2, varscan2
- ARG2 | c.256A>C p.I86L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV99937531; called by muse, mutect2, varscan2
- ARHGAP1 | c.1262A>C p.K421T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100357989; called by muse, mutect2, varscan2
- ARHGAP12 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV60967024; called by muse, mutect2, varscan2
- ARHGAP15 | c.338G>T p.R113I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99712206; called by muse, varscan2
- ARHGAP17 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV51506284, COSV99253764; called by muse, mutect2, varscan2
- ARHGAP24 | c.1541A>G p.N514S (on ENST00000395184 / NM_001025616.3; = p.N421S on NM_031305.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs769996754, COSV99982225; called by muse, mutect2, varscan2
- ARHGAP24 | c.2015G>A p.R672Q (on ENST00000395184 / NM_001025616.3; = p.R579Q on NM_031305.3) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs201180714, COSV51987589; called by muse, mutect2, varscan2
- ARHGAP31 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51788971; called by muse, mutect2, varscan2
- ARHGAP35 | c.1766C>A p.S589* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV101351333, COSV68334315; called by muse, mutect2, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, mutect2, varscan2
- ARHGAP5 | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100565551; called by muse, mutect2, varscan2
- ARHGAP5 | c.4299T>G p.I1433M (on ENST00000345122 / NM_001030055.2; = p.I1432M on NM_001173.3) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV99391976; called by muse, mutect2, varscan2
- ARHGAP6 | c.2680G>A p.A894T (on ENST00000337414 / NM_013427.3; = p.A691T on NM_013423.3) | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100273277; called by muse, mutect2, varscan2
- ARHGAP6 | c.1719C>A p.F573L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57300344; called by muse, mutect2, varscan2
- ARHGAP6 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.037); catalogued as COSV100498650, COSV61623584; called by muse, varscan2
- ARHGAP9 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100712489; called by muse, mutect2, varscan2
- ARHGEF10 | c.2866C>T p.R956C (on ENST00000398564; = p.R931C on NM_014629.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs772945845, COSV50648105; called by muse, mutect2, varscan2
- ARHGEF12 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100755062; called by muse, mutect2, varscan2
- ARHGEF12 | c.4526A>C p.K1509T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.628); catalogued as COSV100755063; called by muse, mutect2, varscan2
- ARHGEF17 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99736190; called by muse, mutect2, varscan2
- ARHGEF26 | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100726650; called by muse, mutect2, varscan2
- ARHGEF28 | c.83A>C p.E28A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV99709598; called by muse, mutect2, varscan2
- ARHGEF28 | c.2899G>T p.E967* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV55268518; called by muse, mutect2, varscan2
- ARHGEF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs866259310, COSV56323686; called by muse, mutect2, varscan2
- ARHGEF39 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100526294; called by muse, mutect2, varscan2
- ARHGEF9 | c.1311T>G p.I437M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99492106; called by muse, mutect2, varscan2
- ARHGEF9 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1569491711, COSV53638489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1B | c.1574G>T p.R525I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51684467, COSV99270610; called by muse, mutect2, varscan2
- ARID2 | c.3722A>C p.K1241T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100536554; called by muse, mutect2, varscan2
- ARID3B | c.1485T>G p.I495M (on ENST00000622429 / NM_001307939.1; = p.I494M on NM_006465.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100654682; called by muse, mutect2, varscan2
- ARID4A | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100793918, COSV100794476; called by muse, mutect2
- ARID4B | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1314403068, COSV51598595; called by muse, mutect2, varscan2
- ARIH1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs770559164, COSV101158779; called by muse, mutect2, varscan2
- ARL6 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs142258123; called by muse, mutect2, varscan2
- ARL8B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766948599, COSV56577028; called by muse, mutect2, varscan2
- ARMC10 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100085797; called by muse, mutect2, varscan2
- ARMC4 | c.425A>C p.N142T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99518827; called by muse, mutect2, varscan2
- ARMCX5 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99863453; called by muse, mutect2, varscan2
- ARNT | c.2370G>T p.*790Yext*65 | Nonstop Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as COSV99648875; called by muse, mutect2, varscan2
- ARNTL | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724803; called by muse, mutect2, varscan2
- ARPIN | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs62000411, COSV100673466; called by muse, mutect2, varscan2
- ARPP21 | c.723A>C p.E241D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99492596; called by muse, mutect2, varscan2
- ARPP21 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99492283; called by muse, mutect2, varscan2
- ARR3 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs760645362, COSV99333781; called by muse, mutect2, varscan2
- ARSF | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100839554, COSV63839052; called by muse, mutect2, varscan2
- ARSG | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71593961; called by muse, mutect2
- ARSI | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV100156043; called by muse, mutect2, varscan2
- ARSI | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60817065, COSV60817994; called by muse, mutect2, varscan2
- ARVCF | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs540820113, COSV54270621; called by muse, mutect2, varscan2
- ASB5 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56671918; called by muse, mutect2, varscan2
- ASH1L | c.3626G>A p.S1209N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100853515; called by muse, mutect2, varscan2
- ASH1L | c.2903A>C p.K968T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100853516; called by muse, mutect2, varscan2
- ASH1L | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV100853518; called by muse, mutect2, varscan2
- ASH1L | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100853519; called by muse, mutect2, varscan2
- ASIC3 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99874725; called by muse, mutect2, varscan2
- ASMTL | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779211999, COSV101187833; called by muse, mutect2, varscan2
- ASNS | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs1265117805, COSV51550431; called by muse, mutect2
- ASNS | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as COSV99446533; called by muse, mutect2, varscan2
- ASPA | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99279217; called by muse, mutect2, varscan2
- ASPG | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV101496429; called by muse, mutect2, varscan2
- ASPH | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as COSV100727689; called by muse, mutect2, varscan2
- ASPM | c.10274C>A p.S3425Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV54127420, COSV54137455, COSV99659149; called by muse, mutect2, varscan2
- ASTE1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs1195834117, COSV53907814; called by muse, mutect2, varscan2
- ASTL | c.1265G>T p.R422I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV60903890; called by muse, mutect2, varscan2
- ASZ1 | c.144A>T p.E48D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as COSV99498156; called by muse, mutect2, varscan2
- ATAD2 | c.2795T>G p.F932C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785006; called by muse, mutect2, varscan2
- ATAD2 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375014962, COSV54886467; called by muse, mutect2, varscan2
- ATAD2B | c.4265G>T p.R1422I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99478099; called by muse, mutect2, varscan2
- ATAD2B | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV99478104, COSV99478132; called by muse, mutect2, varscan2
- ATAD5 | c.2184A>C p.L728F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100430077; called by muse, mutect2, varscan2
- ATAD5 | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100430080; called by muse, mutect2, varscan2
- ATAD5 | c.5021G>T p.R1674I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs371910087, COSV100430082; called by muse, mutect2, varscan2
- ATG16L1 | c.1417T>G p.F473V (on ENST00000392017 / NM_030803.7; = p.F454V on NM_017974.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100731351; called by muse, mutect2, varscan2
- ATG2A | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101034599; called by muse, mutect2, varscan2
- ATG4A | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100564586; called by muse, mutect2, varscan2
- ATL1 | c.853A>T p.K285* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV100613199; called by muse, mutect2, varscan2
- ATP10B | c.1911C>A p.F637L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.062); catalogued as COSV100515388, COSV59159618; called by muse, mutect2, varscan2
- ATP10D | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.515); catalogued as COSV56712236, COSV99905883; called by muse, mutect2, varscan2
- ATP10D | c.4196C>A p.S1399Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.094); catalogued as COSV99904038; called by muse, mutect2
- ATP11A | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52106636, COSV99369333; called by muse, mutect2, varscan2
- ATP11A | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52109089; called by muse, mutect2, varscan2
- ATP11B | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV60029761; called by muse, mutect2, varscan2
- ATP11C | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558309; called by muse, mutect2, varscan2
- ATP12A | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99518055; called by muse, mutect2, varscan2
- ATP12A | c.2617+2T>C p.X873_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99518061; called by muse, mutect2
- ATP13A2 | c.2835C>A p.F945L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1227660193, COSV100454278; called by muse, mutect2, varscan2
- ATP13A4 | c.2236A>G p.N746D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV100710521; called by muse, mutect2, varscan2
- ATP2A2 | c.1385T>A p.L462H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100428779; called by muse, mutect2, varscan2
- ATP4B | c.558C>T p.I186= | Splice Region (SNP) | VAF 27/75 reads (36%) | catalogued as rs372348110; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1479-1G>T p.X493_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100023330; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs765861392, COSV100023333; called by muse, mutect2, varscan2
- ATP6V1C2 | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV99695973; called by muse, mutect2, varscan2
- ATP7A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV58444929; called by muse, mutect2, varscan2
- ATP7A | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100431270, COSV58442856; called by muse, mutect2, varscan2
- ATP8A1 | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046734; called by muse, mutect2, varscan2
- ATP8A2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV54943466, COSV99683072; called by muse, varscan2
- ATP8A2 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54946757; called by muse, varscan2
- ATP8A2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs1465607642, COSV99683080; called by muse, varscan2
- ATP8B1 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99377554; called by muse, mutect2, varscan2
- ATP8B3 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs777333038, COSV59539910; called by muse, mutect2, varscan2
- ATP9B | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as rs147932692; called by muse, mutect2, varscan2
- ATRIP | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100202883; called by muse, mutect2, varscan2
- ATRNL1 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100746539; called by muse, mutect2, varscan2
- ATRX | c.3431G>T p.R1144I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV64886149; called by muse, mutect2, varscan2
- ATRX | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV64881048; called by muse, mutect2, varscan2
- ATXN2L | c.787A>C p.N263H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV100294808; called by muse, mutect2, varscan2
- ATXN3 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs377031212; called by muse, mutect2, varscan2
- AUNIP | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100961911; called by muse, mutect2, varscan2
- AURKC | c.543G>T p.K181N (on ENST00000302804 / NM_001015878.2; = p.K147N on NM_003160.3) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100248915; called by muse, mutect2, varscan2
- AURKC | c.625G>A p.E209K (on ENST00000302804 / NM_001015878.2; = p.E175K on NM_003160.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100248917; called by muse, mutect2, varscan2
- AXDND1 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1482806456, COSV100858537; called by muse, mutect2, varscan2
- AXIN2 | c.573G>T p.L191F | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196761; called by muse, mutect2, varscan2
- B3GALNT1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748945246, CD1314793, COSV100252091; called by muse, mutect2, varscan2
- B3GNT2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs767753065, COSV57345856; called by muse, mutect2, varscan2
- B4GALNT4 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV57323121, COSV57323977; called by muse, mutect2
- B4GALT3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776066366, COSV100157819; called by muse, mutect2, varscan2
- B4GALT4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1314966890, COSV100785829; called by muse, mutect2, varscan2
- BABAM1 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.031); catalogued as COSV99394414; called by muse, mutect2, varscan2
- BAG5 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99914950; called by muse, mutect2, varscan2
- BAHCC1 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as COSV100311881; called by muse, mutect2, varscan2
- BAIAP2 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.718); catalogued as rs761731419, COSV100348526; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1233G>T p.M411I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs748871895, COSV100260178; called by muse, mutect2, varscan2
- BANK1 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs375068296, COSV100536603; called by muse, varscan2
- BAP1 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs144881611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.3826G>C p.E1276Q | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99681023; called by muse, mutect2, varscan2
- BBOF1 | c.1323G>T p.L441F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100620923; called by muse, mutect2, varscan2
- BBS2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as rs374487957, COSV55328491; called by muse, mutect2, varscan2
- BBS4 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99166495; called by mutect2, varscan2
- BBX | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); catalogued as COSV100361987, COSV57880187, COSV57881301; called by muse, mutect2, varscan2
- BCHE | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100012005, COSV52253121; called by muse, mutect2, varscan2
- BCL11B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs767394342, COSV100596079, COSV61734180; called by muse, mutect2, varscan2
- BCS1L | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1004879625, COSV55308087; called by muse, mutect2, varscan2
- BDP1 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100703347; called by muse, mutect2, varscan2
- BECN1 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100831166; called by muse, mutect2, varscan2
- BEND4 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV101549777; called by muse, mutect2, varscan2
- BEND7 | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100346844; called by muse, mutect2, varscan2
- BEND7 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100346852; called by muse, mutect2, varscan2
- BEST1 | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV100077269; called by muse, mutect2, varscan2
- BEX3 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs770614081, COSV100244344; called by muse, mutect2, varscan2
- BGN | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV100525244; called by muse, mutect2, varscan2
- BHMT2 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.352); catalogued as COSV99670214; called by muse, mutect2, varscan2
- BICC1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs201753164, COSV65856907; called by muse, mutect2, varscan2
- BICD1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99862727; called by muse, mutect2, varscan2
- BIRC5 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV56956138; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57278938; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4228G>A p.D1410N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV63245687; called by muse, mutect2, varscan2
- BLVRA | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as rs748363460, COSV99646052; called by muse, mutect2, varscan2
- BMP8B | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs376816899; called by muse, mutect2, varscan2
- BMS1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768970108, COSV100996649; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BMX | c.1721T>G p.F574C | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564564; called by muse, mutect2, varscan2
- BNC2 | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs201719018, COSV101036558, COSV66163854; called by muse, mutect2, varscan2
- BNIP5 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs151027628; called by muse, mutect2, varscan2
- BNIPL | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99764730; called by muse, mutect2, varscan2
- BOD1L1 | c.1621T>G p.L541V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV99239906; called by muse, mutect2, varscan2
- BOP1 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV100266036; called by muse, mutect2, varscan2
- BORA | c.574C>A p.H192N (on ENST00000613797; = p.H117N on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100909731; called by muse, mutect2, varscan2
- BPGM | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100790215; called by muse, mutect2, varscan2
- BRCA1 | c.3646T>G p.L1216V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100524704; called by muse, mutect2, varscan2
- BRCA2 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV101204493; called by muse, mutect2, varscan2
- BRCA2 | c.8780G>A p.R2927K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as rs1555288372, COSV101204494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRDT | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100746284; called by muse, mutect2, varscan2
- BRINP1 | c.2107A>G p.I703V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99776248; called by muse, mutect2, varscan2
- BRIP1 | c.2668A>C p.K890Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.351); catalogued as COSV99370583; called by muse, mutect2, varscan2
- BRIP1 | c.2454A>C p.E818D | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV99370588; called by muse, mutect2, varscan2
- BRSK2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs762994850, COSV100372941; called by muse, mutect2, varscan2
- BRWD1 | c.2669G>A p.R890Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as COSV100313734; called by muse, mutect2
- BRWD1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs760850324, COSV60901666; called by muse, varscan2
- BRWD3 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1368496222, COSV64751478; called by muse, mutect2, varscan2
- BRWD3 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100956301; called by muse, mutect2, varscan2
- BST1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53946229; called by muse, mutect2, varscan2
- BTAF1 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.733); catalogued as COSV99795561; called by muse, mutect2, varscan2
- BTBD7 | c.871T>G p.L291V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.389); catalogued as COSV54134862; called by muse, mutect2, varscan2
- BTN1A1 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV55069626; called by muse, mutect2, varscan2
- BUD31 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs568467012, COSV52863230; called by muse, mutect2, varscan2
- BVES | c.497A>C p.K166T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as COSV100115029, COSV100115164; called by muse, mutect2, varscan2
- BZW1 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as rs1251721401, COSV101284541; called by muse, mutect2, varscan2
- C11orf65 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1565656821, COSV101262869; called by muse, mutect2, varscan2
- C12orf40 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100210416; called by muse, mutect2, varscan2
- C12orf40 | c.1040G>T p.R347I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV100210420; called by muse, mutect2, varscan2
- C12orf50 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100072373; called by muse, mutect2, varscan2
- C12orf66 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100320844; called by mutect2, varscan2
- C16orf92 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV99662510; called by muse, mutect2, varscan2
- C17orf49 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as COSV101143388; called by muse, mutect2, varscan2
- C1GALT1C1 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV58974017; called by muse, mutect2, varscan2
- C1GALT1C1L | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs910474337, COSV56749520; called by muse, mutect2, varscan2
- C1QC | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs777624236, COSV65889431; called by muse, mutect2, varscan2
- C1orf100 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs762477027, COSV57374505; called by muse, mutect2, varscan2
- C1orf116 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs569420144, COSV100847966; called by muse, mutect2, varscan2
- C1orf141 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100924325, COSV100924365; called by muse, mutect2, varscan2
- C1orf141 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.72); catalogued as COSV63992623; called by muse, mutect2, varscan2
- C1orf74 | c.271A>C p.N91H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV99162209; called by muse, mutect2, varscan2
- C20orf194 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs374956285, COSV52694220; called by muse, mutect2, varscan2
- C2CD2L | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs750402851, COSV60883825; called by muse, mutect2, varscan2
- C2CD3 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100487052; called by muse, mutect2
- C2CD5 | c.2868C>A p.N956K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100448902; called by muse, mutect2, varscan2
- C2CD6 | c.370+1G>T p.X124_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99633839; called by muse, mutect2, varscan2
- C2orf78 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101281008; called by muse, mutect2, varscan2
- C3orf14 | c.24A>T p.E8D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99223806; called by muse, varscan2
- C3orf20 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99514291; called by muse, mutect2, varscan2
- C5 | c.3761C>A p.A1254D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99798321; called by muse, mutect2, varscan2
- C5orf49 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs761410234, COSV57883149; called by muse, mutect2, varscan2
- C6 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99667438, COSV99668001; called by muse, mutect2, varscan2
- C6orf118 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs368176728; called by muse, mutect2, varscan2
- C8orf33 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100510574; called by muse, mutect2, varscan2
- C8orf34 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1461696168, COSV100298747; called by muse, varscan2
- C9orf135 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV101019898; called by muse, mutect2, varscan2
- CA5B | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100590776; called by muse, mutect2, varscan2
- CACHD1 | c.2804T>G p.F935C | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99262814; called by muse, mutect2, varscan2
- CACNA1D | c.6259G>T p.E2087* (on ENST00000350061 / NM_001128840.3; = p.E2107* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA1E | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs1484841139, COSV62437802; called by muse, mutect2, varscan2
- CACNA1F | c.4275C>A p.F1425L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100545126; called by muse, mutect2, varscan2
- CACNA1F | c.3351C>A p.F1117L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100544248; called by muse, mutect2, varscan2
- CACNA1I | c.5203G>A p.D1735N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60813837; called by muse, mutect2, varscan2
- CACNA1S | c.1948+2T>C p.X650_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as rs1185268927, COSV100755189; called by muse, mutect2, varscan2
- CACNA2D1 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV62375168; called by muse, mutect2, varscan2
- CACNA2D4 | c.3409C>T p.R1137W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs777584286, COSV99766072; called by muse, mutect2, varscan2
- CACUL1 | c.992T>G p.F331C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100432621; called by muse, mutect2, varscan2
- CAD | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778916575, COSV99255394; called by muse, mutect2, varscan2
- CADPS | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.952); catalogued as COSV99339742; called by muse, mutect2, varscan2
- CADPS2 | c.3170G>T p.R1057I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.794); catalogued as COSV100464392; called by muse, mutect2, varscan2
- CALCOCO1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs376685260, COSV50425439; called by muse, mutect2, varscan2
- CALCR | c.968C>T p.A323V (on ENST00000649521 / NM_001164737.2; = p.A307V on NM_001742.4) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as rs527875590, COSV100810692, COSV64006212; called by muse, mutect2, varscan2
- CALCRL | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.281); catalogued as COSV66475427; called by muse, varscan2
- CALCRL | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV101130917, COSV101131009; called by muse, varscan2
- CALHM6 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV100889460; called by muse, mutect2, varscan2
- CAMK2A | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.066); catalogued as COSV100652071; called by muse, mutect2, varscan2
- CAMK2A | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62245874; called by muse, mutect2, varscan2
- CAMK4 | c.321A>G p.I107M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99999822; called by muse, mutect2, varscan2
- CAMSAP2 | c.4376T>G p.L1459* (on ENST00000236925 / NM_001297707.2; = p.L1448* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99373769; called by muse, mutect2
- CAND1 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV101598282; called by muse, mutect2, varscan2
- CAP2 | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV100012702; called by muse, mutect2, varscan2
- CAPG | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV99809503; called by muse, mutect2, varscan2
- CAPN9 | c.1120T>G p.F374V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55241390; called by muse, mutect2, varscan2
- CARD6 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54566059, COSV99621029; called by muse, mutect2, varscan2
- CARD6 | c.1550G>T p.R517I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs774841187, COSV54566069; called by muse, mutect2, varscan2
- CARMIL3 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs148593427; called by muse, mutect2, varscan2
- CASD1 | c.1698T>G p.F566L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV99802820; called by muse, mutect2, varscan2
- CASD1 | c.1927C>A p.L643M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99802823; called by muse, mutect2, varscan2
- CASK | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1310982151, COSV59363268; called by muse, mutect2, varscan2
- CASKIN2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs370315404; called by muse, mutect2, varscan2
- CASP1 | c.1120C>T p.R374* (on ENST00000436863 / NM_033292.4; = p.R353* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs750821528, COSV52832044; called by muse, varscan2
- CASP1 | c.517T>G p.F173V (on ENST00000436863 / NM_033292.4; = p.F152V on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782815; called by muse, mutect2, varscan2
- CASP5 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs1397399939, COSV52827519; called by muse, mutect2, varscan2
- CASP8 | c.538G>T p.E180* (on ENST00000432109 / NM_033355.3; = p.E212* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV51861924; called by muse, mutect2, varscan2
- CASP8AP2 | c.1673T>A p.F558Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99387269; called by muse, mutect2, varscan2
- CASS4 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV64388606; called by muse, varscan2
- CASS4 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100824801; called by muse, varscan2
- CATSPERD | c.210A>C p.Q70H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV101062687; called by muse, mutect2, varscan2
- CATSPERG | c.2449A>C p.I817L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99286732; called by muse, mutect2, varscan2
- CAVIN4 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.372); catalogued as rs1194100440, COSV100293332; called by muse, mutect2, varscan2
- CBFA2T2 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs374883285; called by muse, mutect2, varscan2
- CBFA2T3 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as rs749479357, COSV51927200; called by muse, mutect2, varscan2
- CBLB | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs1476526903, COSV51430548; called by muse, mutect2, varscan2
- CBLL2 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV100081670; called by muse, mutect2, varscan2
- CBX6 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as COSV99328202; called by muse, varscan2
- CC2D2B | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373755580; called by muse, mutect2, varscan2
- CCAR1 | c.3289T>G p.L1097V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.987); catalogued as rs1040189895, COSV99771223; called by muse, mutect2, varscan2
- CCDC102B | c.805A>C p.K269Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV100104117; called by muse, mutect2, varscan2
- CCDC103 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.5); catalogued as COSV99493473; called by muse, mutect2, varscan2
- CCDC110 | c.2282A>C p.E761A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV100294067; called by muse, mutect2, varscan2
- CCDC110 | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100294072; called by muse, mutect2, varscan2
- CCDC112 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101100492; called by muse, mutect2, varscan2
- CCDC112 | c.-10-1G>T | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as COSV101100493; called by muse, mutect2, varscan2
- CCDC121 | c.84A>T p.E28D | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99270327; called by muse, mutect2, varscan2
- CCDC125 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as rs771037105, COSV101143677; called by muse, mutect2, varscan2
- CCDC146 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs770508290, COSV53548067; called by muse, varscan2
- CCDC158 | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV101187301; called by muse, mutect2, varscan2
- CCDC158 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 31/39 reads (79%) | catalogued as COSV66356356; called by muse, mutect2, varscan2
- CCDC171 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99901336; called by muse, mutect2, varscan2
- CCDC171 | c.2546A>C p.K849T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52644192; called by muse, mutect2, varscan2
- CCDC173 | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV101352363; called by muse, mutect2, varscan2
- CCDC180 | c.3697G>T p.D1233Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100827068; called by muse, mutect2, varscan2
- CCDC180 | c.4775C>T p.S1592L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs566316997, COSV63826671; called by muse, mutect2, varscan2
- CCDC184 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100343999; called by muse, mutect2, varscan2
- CCDC186 | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100991040; called by muse, mutect2, varscan2
- CCDC190 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as COSV100905836; called by muse, varscan2
- CCDC190 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV63362841; called by muse, varscan2
- CCDC198 | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99371312; called by muse, mutect2
- CCDC25 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100738302; called by muse, mutect2, varscan2
- CCDC28A | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV100236465, COSV100236563; called by muse, mutect2, varscan2
- CCDC30 | c.1499G>T p.R500I (on ENST00000340612; = p.R457I on NM_001080850.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV100501517, COSV59609412; called by muse, mutect2, varscan2
- CCDC30 | c.1937T>G p.L646* (on ENST00000340612; = p.L603* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV100501519; called by muse, mutect2, varscan2
- CCDC32 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100785981; called by muse, mutect2, varscan2
- CCDC33 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs763126342, COSV100351623; called by mutect2, varscan2
- CCDC39 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as COSV56481950, COSV99869949; called by muse, mutect2, varscan2
- CCDC40 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs375800869; called by muse, mutect2, varscan2
- CCDC59 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV50259297; called by muse, mutect2, varscan2
- CCDC68 | c.499T>A p.L167M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100491913; called by muse, mutect2, varscan2
- CCDC73 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs1302619987, COSV100067976, COSV58796349; called by muse, mutect2, varscan2
- CCDC74B | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100134590; called by muse, mutect2, varscan2
- CCDC81 | c.1205A>C p.K402T (on ENST00000445632 / NM_001156474.2; = p.K312T on NM_021827.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99564606; called by muse, mutect2, varscan2
- CCDC85A | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.949); catalogued as COSV101339497; called by muse, mutect2, varscan2
- CCDC87 | c.2248C>A p.R750S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100040090, COSV59580176; called by muse, mutect2, varscan2
- CCDC87 | c.1488G>T p.K496N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100040091; called by muse, mutect2, varscan2
- CCDC87 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs141059944; called by muse, mutect2, varscan2
- CCDC88A | c.5594C>A p.S1865Y (on ENST00000436346 / NM_001365480.1; = p.S1837Y on NM_018084.5) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV55057178; called by muse, mutect2, varscan2
- CCDC96 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as rs753773609, COSV59508510; called by muse, mutect2, varscan2
- CCL7 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99565596; called by muse, mutect2, varscan2
- CCM2L | c.122C>A p.S41* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV52949007, COSV99395291; called by muse, mutect2, varscan2
- CCNB3 | c.1458G>T p.K486N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99329435; called by muse, varscan2
- CCNB3 | c.1471T>G p.L491V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV99329438; called by muse, varscan2
- CCNB3 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52072336, COSV99329441; called by muse, mutect2, varscan2
- CCNB3 | c.2180A>C p.K727T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99329444; called by muse, mutect2, varscan2
- CCNB3 | c.4049C>A p.S1350Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.439); catalogued as COSV52081163; called by muse, mutect2, varscan2
- CCNL1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99904246; called by muse, mutect2, varscan2
- CCT3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs947249193, COSV99827405; called by muse, mutect2, varscan2
- CCT4 | c.381G>A p.G127= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as COSV101075290; called by muse, mutect2, varscan2
- CCT6B | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100030863; called by muse, mutect2, varscan2
- CD14 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs748936952, COSV100117587; called by muse, mutect2, varscan2
- CD163 | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV100775995, COSV63130889; called by muse, mutect2, varscan2
- CD163 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.479); catalogued as COSV63132019; called by muse, mutect2, varscan2
- CD180 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99842309; called by muse, mutect2, varscan2
- CD200R1L | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.344); catalogued as COSV101236607; called by muse, mutect2
- CD209 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs187439891, COSV52649272; called by muse, mutect2, varscan2
- CD247 | c.305G>T p.R102I (on ENST00000362089 / NM_198053.3; = p.R101I on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100758432; called by muse, mutect2, varscan2
- CD40LG | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1350282799, COSV65699086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD40LG | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV65698991; called by muse, mutect2, varscan2
- CD53 | c.505-2A>G p.X169_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99602302; called by muse, mutect2, varscan2
- CD70 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.457); catalogued as COSV99835617; called by muse, mutect2, varscan2
- CD79B | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs868652684, COSV50076455, COSV50077867; called by muse, mutect2, varscan2
- CD99 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101152313; called by muse, mutect2, varscan2
- CDC20B | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99697186; called by muse, mutect2, varscan2
- CDC25B | c.286G>A p.E96K (on ENST00000245960 / NM_021873.3; = p.E82K on NM_004358.4) | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs761763027, COSV55655489; called by muse, mutect2, varscan2
- CDC27 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as rs77685276; called by muse, mutect2, varscan2
- CDC42BPA | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs370050361, COSV62008138; called by muse, mutect2, varscan2
- CDC5L | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV65175931; called by muse, mutect2, varscan2
- CDCA7L | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100651166; called by muse, mutect2, varscan2
- CDH11 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1203582809, COSV99219219; called by muse, mutect2, varscan2
- CDH12 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV66425492; called by muse, mutect2, varscan2
- CDH12 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765565044, COSV101202350, COSV66397071; called by muse, mutect2, varscan2
- CDH5 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV58515726; called by muse, mutect2, varscan2
- CDH7 | c.1599G>T p.L533F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100542838; called by muse, mutect2, varscan2
- CDK11B | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.839); catalogued as rs748349947, COSV58337332; called by muse, mutect2
- CDK15 | c.653A>G p.Q218R (on ENST00000652192 / NM_001366386.2; = p.Q167R on NM_139158.2) | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99643458; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5491A>C p.K1831Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100575630; called by muse, mutect2
- CDKAL1 | c.1374C>A p.F458L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.216); catalogued as COSV51181176; called by mutect2, varscan2
- CDKL2 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100277084, COSV56733967; called by muse, mutect2, varscan2
- CDKL4 | c.234A>C p.L78F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101115432; called by muse, mutect2, varscan2
- CDO1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs766064742, COSV51665160; called by muse, mutect2
- CDRT15 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV101415152; called by muse, mutect2, varscan2
- CDX4 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100999144; called by muse, varscan2
- CEACAM4 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.678); catalogued as rs1276485852, COSV55732230; called by muse, mutect2, varscan2
- CEACAM8 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV54990424, COSV54991257; called by muse, mutect2, varscan2
- CECR2 | c.1021C>A p.L341I (on ENST00000342247 / NM_001290047.2; = p.L178I on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52837219; called by muse, mutect2, varscan2
- CECR2 | c.4181A>T p.H1394L (on ENST00000342247 / NM_001290047.2; = p.H1210L on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV99378623; called by muse, mutect2, varscan2
- CELSR2 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as rs761369782, COSV99604384; called by muse, varscan2
- CENPC | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs772093973, COSV56622197; called by muse, mutect2, varscan2
- CENPF | c.5812G>T p.D1938Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776282020, COSV100871813; called by muse, mutect2, varscan2
- CENPF | c.6196G>T p.E2066* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as rs1558186264, COSV100871474; called by muse, mutect2, varscan2
- CENPI | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99515604; called by muse, mutect2, varscan2
- CENPI | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs768476710, COSV54501852, COSV99515609; called by mutect2, varscan2
- CENPJ | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs1222002107, COSV101121467; called by muse, mutect2, varscan2
- CENPJ | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV101121545; called by muse, mutect2, varscan2
- CEP120 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs751634657, COSV60264390; called by muse, mutect2, varscan2
- CEP126 | c.3020C>A p.S1007Y | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as COSV54824852; called by muse, mutect2, varscan2
- CEP135 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV57260784, COSV99954689; called by muse, mutect2, varscan2
- CEP152 | c.4981C>T p.R1661C (on ENST00000380950 / NM_001194998.2; = p.R1605C on NM_014985.4) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs369971070; called by muse, mutect2, varscan2
- CEP152 | c.4133A>C p.K1378T (on ENST00000380950 / NM_001194998.2; = p.K1322T on NM_014985.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as COSV100358993; called by muse, mutect2, varscan2
- CEP152 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100358994; called by muse, varscan2
- CEP170 | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs773315365, COSV60511643; called by muse, mutect2, varscan2
- CEP170 | c.2373T>G p.N791K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV100317480; called by muse, mutect2, varscan2
- CEP250 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as rs1051944154, COSV61169712; called by muse, mutect2, varscan2
- CEP290 | c.6535A>C p.K2179Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100469255; called by muse, varscan2
- CEP290 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs760934388, COSV58357676; called by muse, mutect2, varscan2
- CEP290 | c.3132G>T p.K1044N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs762342726, COSV58351236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP290 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs753374614, COSV58353842, COSV58355012; called by muse, mutect2, varscan2
- CEP350 | c.8860C>G p.L2954V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100854974; called by muse, mutect2, varscan2
- CEP44 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs769157129, COSV56658367; called by muse, mutect2, varscan2
- CEP57L1 | c.683A>C p.K228T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV100425902; called by muse, mutect2, varscan2
- CEP70 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV53875935, COSV99389395; called by muse, mutect2, varscan2
- CEP78 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99450735; called by muse, mutect2, varscan2
- CEP85L | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); catalogued as COSV100874278; called by muse, mutect2, varscan2
- CEP95 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV101616325; called by muse, mutect2, varscan2
- CER1 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV101097898; called by muse, mutect2, varscan2
- CER1 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.233); catalogued as COSV101097901; called by muse, mutect2, varscan2
- CES1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762825525, COSV62089036; called by muse, mutect2, varscan2
- CES3 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs376329904, COSV57593280; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.738); catalogued as rs760491203, COSV100291914; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as rs1217385253, COSV99267448; called by muse, mutect2, varscan2
- CFAP43 | c.3578T>G p.I1193S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV100829401; called by muse, mutect2, varscan2
- CFAP44 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1211874871, COSV99869516; called by muse, mutect2, varscan2
- CFAP46 | c.6657C>A p.F2219L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV54152516, COSV99585240; called by muse, mutect2, varscan2
- CFAP47 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV52891780, COSV99935511; called by muse, mutect2, varscan2
- CFAP58 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV57211635; called by muse, varscan2
- CFAP58 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV100459031; called by muse, mutect2, varscan2
- CFAP58 | c.1694G>A p.R565K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100866128; called by muse, mutect2, varscan2
- CFAP58 | c.2023A>C p.N675H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100866129; called by muse, mutect2, varscan2
- CFAP61 | c.53G>T p.R18I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843524, COSV99845777; called by muse, mutect2, varscan2
- CFAP61 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55632536, COSV99845313; called by muse, mutect2, varscan2
- CFAP70 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 33/103 reads (32%) | catalogued as COSV100160844; called by muse, mutect2, varscan2
- CFAP70 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV60283058; called by muse, mutect2, varscan2
- CFAP91 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.021); catalogued as COSV99847307; called by muse, mutect2, varscan2
- CFAP94 | c.142C>T p.R48* (on ENST00000320267 / NM_001352064.2; = p.R54* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs546158870, COSV57232145; called by muse, varscan2
- CFAP94 | c.82G>A p.E28K (on ENST00000320267 / NM_001352064.2; = p.E34K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs1452073854, COSV100209558, COSV57232447; called by muse, mutect2, varscan2
- CFH | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs897349638, COSV100809895; called by muse, mutect2, varscan2
- CFH | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as COSV66406615; called by muse, mutect2, varscan2
- CFHR5 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99889285; called by muse, mutect2, varscan2
- CFP | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1054420139, COSV99901588; called by muse, mutect2, varscan2
- CGAS | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100943688; called by muse, mutect2, varscan2
- CGREF1 | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV99565291; called by muse, mutect2, varscan2
- CHCHD3 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99366560; called by muse, mutect2, varscan2
- CHD1 | c.3010A>C p.N1004H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV99399647; called by muse, mutect2, varscan2
- CHD1 | c.1792A>C p.K598Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99399648; called by muse, mutect2, varscan2
- CHD2 | c.4250G>T p.R1417I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV101245647; called by muse, mutect2, varscan2
- CHD4 | c.2518G>T p.E840* (on ENST00000357008 / NM_001363606.2; = p.E853* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100538523; called by muse, mutect2, varscan2
- CHD4 | c.2415G>T p.E805D (on ENST00000357008 / NM_001363606.2; = p.E818D on NM_001273.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV100538525; called by muse, mutect2, varscan2
- CHD5 | c.2594G>A p.S865N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV99314296; called by muse, mutect2, varscan2
- CHD5 | c.2301G>T p.E767D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99314297; called by muse, mutect2, varscan2
- CHD5 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99314299; called by muse, mutect2, varscan2
- CHD8 | c.3016C>A p.L1006I (on ENST00000646647 / NM_001170629.2; = p.L727I on NM_020920.4) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV101303168; called by muse, mutect2, varscan2
- CHI3L2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1039610150, COSV63874430; called by muse, mutect2, varscan2
- CHI3L2 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV100869303; called by muse, mutect2, varscan2
- CHIA | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs752677743, COSV58474195; called by muse, mutect2
- CHKB | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs200919604, COSV56414909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs750674722, COSV56607646; called by muse, mutect2, varscan2
- CHL1 | c.865G>T p.E289* (on ENST00000397491 / NM_001253387.1; = p.E305* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99851727; called by muse, mutect2, varscan2
- CHM | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.23); catalogued as rs1202402597, COSV100753494; called by muse, mutect2, varscan2
- CHODL | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100166933, COSV54731287; called by muse, mutect2, varscan2
- CHRM2 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV57766199; called by muse, mutect2, varscan2
- CHRNA6 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99373301; called by muse, mutect2, varscan2
- CHST10 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51804617, COSV99959118; called by muse, mutect2, varscan2
- CHST15 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs375217023; called by muse, mutect2, varscan2
- CHST2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58885590; called by muse, varscan2
- CHTOP | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); catalogued as rs774613264, COSV100904695; called by muse, mutect2, varscan2
- CIDEA | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs140796846, COSV100255117; called by muse, mutect2, varscan2
- CKAP2 | c.349G>A p.D117N (on ENST00000378037 / NM_001098525.2; = p.D116N on NM_018204.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.856); catalogued as rs1408011553, COSV99318386; called by muse, varscan2
- CKS2 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100068871; called by muse, mutect2, varscan2
- CLASP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs1189932217, COSV55313347; called by muse, mutect2, varscan2
- CLASP2 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs554149266, COSV56280338; called by muse, mutect2, varscan2
- CLASP2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as rs755785792, COSV56279547; called by muse, mutect2, varscan2
- CLCA2 | c.906C>A p.F302L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs758991075, COSV100991622, COSV65287208; called by muse, mutect2, varscan2
- CLCA4 | c.914G>T p.R305I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99760479; called by muse, mutect2, varscan2
- CLCN3 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100641544; called by muse, mutect2, varscan2
- CLCNKB | c.1581G>T p.K527N | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100990366; called by muse, mutect2, varscan2
- CLDN17 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729298; called by muse, mutect2, varscan2
- CLEC17A | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.672); catalogued as COSV60429176; called by muse, mutect2, varscan2
- CLEC4M | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs762825731, COSV50217050, COSV99940709; called by muse, mutect2, varscan2
- CLGN | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100346735; called by muse, varscan2
- CLK1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs568116164, COSV100362367; called by muse, mutect2, varscan2
- CLNK | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs763460829, COSV57010736; called by muse, mutect2, varscan2
- CLPTM1L | c.1335C>A p.F445L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100307201; called by muse, mutect2, varscan2
- CLSPN | c.1580-1G>A p.X527_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99231236; called by muse, mutect2, varscan2
- CLTCL1 | c.2553A>C p.K851N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV99595466; called by muse, mutect2, varscan2
- CLTCL1 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.617); catalogued as COSV99595468; called by muse, mutect2, varscan2
- CLUAP1 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100489602, COSV58894697; called by muse, mutect2, varscan2
- CMTM5 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs139744261; called by muse, varscan2
- CMTR2 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV100579245, COSV57604422; called by muse, mutect2, varscan2
- CMYA5 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101484201, COSV71409184, COSV71409886; called by muse, mutect2, varscan2
- CMYA5 | c.5542G>T p.D1848Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs778272543, COSV101484203, COSV71409364; called by muse, mutect2, varscan2
- CMYA5 | c.8726C>A p.S2909Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV71405166; called by muse, mutect2, varscan2
- CNGA1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198139574, COSV62053154; called by muse, mutect2, varscan2
- CNKSR2 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.168); catalogued as COSV99669215; called by muse, mutect2, varscan2
- CNKSR2 | c.3038C>A p.S1013Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV101069965; called by muse, varscan2
- CNNM1 | c.1367T>G p.I456S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100763931; called by muse, mutect2, varscan2
- CNNM1 | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100763933; called by muse, mutect2, varscan2
4,337 further variants in this file (3,337 protein-altering or splice-affecting, 874 silent, 126 other) are not listed here.
